Gene-level copy-number profile of tumor specimen TCGA-AN-A0XV-01A from TCGA case TCGA-AN-A0XV, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 67.8 years (24,779 days).
Specimen TCGA-AN-A0XV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.7754e179-0e81-431d-926e-c24be0e6b4e1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AN-A0XV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bb13bec8-7dee-4fb5-a7c6-e497938b6d83

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 38; copy number 1: 3,068; copy number 2: 55,180; copy number 3: 873; copy number 4: 138; copy number 5: 72; copy number 6: 49; copy number 7: 67; copy number 8: 45; copy number 9: 34; copy number 10: 72; copy number 12: 50; copy number 13: 65; copy number 15: 50; copy number 18: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AN-A0XV-01A-11D-A107-01): tumor purity 0.52, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 38 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,695,176–24,905,735, 36 genes: KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5.
- chr9:28,863,626–28,888,955, 2 genes: MIR876, MIR873.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 517 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:62,658,343–62,864,181, 3 genes, copy number 5: AC090577.1, XRCC6P4, SRPK2P.
- chr8:66,126,896–67,746,378, 36 genes, copy number 6–12 (within-gene range 4–12): TRIM55, CRH, LINC00967, AC009879.4, RRS1-AS1, RRS1, AC009879.2, AC009879.3, ADHFE1, AC009879.1, VXN, RNU6-1324P, MYBL1, VCPIP1, Y_RNA, C8orf44-SGK3, C8orf44, SGK3, PTTG3P, MCMDC2, SNHG6, SNORD87, TCF24, PPP1R42, AC110998.1, COPS5, CSPP1, RNA5SP268, AC087359.1, ARFGEF1, AC021321.2, AC021321.1, AC011037.1, CPA6, NACAP10, AC022874.1.
- chr8:79,259,402–88,019,113, 148 genes, copy number 5–12 (broad region; genes not listed).
- chr8:89,757,806–100,683,574, 204 genes, copy number 7–18 (broad region; genes not listed).
- chr8:101,686,542–104,589,024, 63 genes, copy number 6–10 (broad region; genes not listed).
- chr8:104,699,479–104,703,555, 1 gene, copy number 6: AC012564.1.
- chr8:112,222,928–113,436,939, 1 gene, copy number 7 (within-gene range 3–9): CSMD3.
- chr8:113,376,669–120,445,402, 61 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,068. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
